Somatic mutation profile of tumor specimen TCGA-DZ-6131-01A (aliquot TCGA-DZ-6131-01A-11D-1961-08) from TCGA case TCGA-DZ-6131, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 31.4 years (11,487 days).
Specimen TCGA-DZ-6131-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91b37991-b97b-4eeb-a5a8-fd9f705607c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DZ-6131-11A (Solid Tissue Normal), aliquot TCGA-DZ-6131-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df5a5054-332d-461d-a82d-a7fc1b8c4207

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 13, Silent 9, Splice Region 1, Splice Site 1, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.3091G>C p.A1031P (on ENST00000272895 / NM_173076.3; = p.A713P on NM_015657.3) | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55963154, COSV55963327; called by muse, mutect2, varscan2
- ADAM30 | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs779652474, COSV65561365; called by muse, mutect2, varscan2
- AIM2 | c.831G>C p.K277N | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV63700225; called by muse, mutect2, varscan2
- DAPP1 | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56451781; called by muse, mutect2, varscan2
- FAM47B | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs748787682, COSV61454213; called by muse, mutect2, varscan2
- GALNT7 | c.1267-1G>A p.X423_splice | Splice Site (SNP) | VAF 51/157 reads (32%) | catalogued as COSV53931273; called by muse, mutect2, varscan2
- GLUL | c.302T>A p.V101D | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100092088, COSV59382492; called by muse, mutect2, varscan2
- IQSEC2 | c.3059G>C p.S1020T (on ENST00000642864 / NM_001111125.3; = p.S815T on NM_015075.2) | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated (0.34); PolyPhen benign (0.155); catalogued as COSV64726236; called by muse, mutect2, varscan2
- MAGEL2 | c.2652G>C p.K884N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58567650; called by muse, mutect2, varscan2
- MGRN1 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52151601; called by muse, mutect2, varscan2
- MTIF2 | c.984C>T p.G328= | Splice Region (SNP) | VAF 10/80 reads (13%) | catalogued as rs540448511, COSV55052036; called by mutect2, varscan2
- PCDH8 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (1); catalogued as COSV58813297, COSV58813836; called by muse, mutect2, varscan2
- PPP1R12A | c.1261A>C p.I421L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54109691; called by muse, mutect2, varscan2
- RXYLT1 | c.263T>G p.L88* | Nonsense Mutation (SNP) | VAF 82/223 reads (37%) | catalogued as COSV54168791; called by muse, mutect2, varscan2
- TTLL6 | c.1945A>C p.N649H (on ENST00000393382 / NM_001130918.3; = p.N342H on NM_173623.3) | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs975218322, COSV64977688; called by muse, mutect2, varscan2
- ZCCHC17 | c.665A>C p.D222A | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV60002626; called by muse, mutect2, varscan2
- SHOC1 | c.3795_3797del p.R1266del | In Frame Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- WDR37 | c.1303_1306del p.F435Ifs*66 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- A2ML1 | c.1830C>T p.R610= | Silent (SNP) | VAF 12/173 reads (7%) | catalogued as COSV55292454; called by muse, mutect2
- C1QTNF2 | c.273C>T p.G91= (on ENST00000393975; = p.G46= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV67432845; called by muse, mutect2, varscan2
- CMTM1 | c.509G>A p.*170= (on ENST00000457188 / NM_181269.3; = p.*287= on NM_052999.4) | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV51748963; called by muse, mutect2, varscan2
- KRTAP10-10 | c.39C>T p.C13= | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as COSV59966851; called by mutect2, varscan2
- MUC2 | c.1878T>C p.P626= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as rs764896646; called by muse, mutect2, varscan2
- PTPN13 | c.4710C>T p.V1570= (on ENST00000411767 / NM_080683.3; = p.V1551= on NM_006264.3) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV57409581; called by muse, mutect2, varscan2
- TEX15 | c.8202A>G p.Q2734= (on ENST00000256246; = p.Q3117= on NM_001350162.2) | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs780534986, COSV56347977; called by muse, mutect2, varscan2
- ZBTB21 | c.435A>G p.Q145= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV60404526; called by muse, mutect2, varscan2
- ZDBF2 | c.2322G>A p.R774= | Silent (SNP) | VAF 51/320 reads (16%) | catalogued as rs778537783, COSV65627176; called by muse, mutect2, varscan2
